Somatic mutation profile of tumor specimen BA2563D (aliquot aq-BA2563D) from BEATAML1.0 case 2493, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.9 years (22,591 days).
Specimen BA2563D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfb29efd-5dba-4370-b8c1-3d18260773fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2177D (Solid Tissue Normal), aliquot aq-BA2177D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd15b643-8820-46cc-b1a6-2278e68fff18

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3, Splice Site 2, In Frame Ins 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1780_1800dup p.F594_D600dup | In Frame Ins (INS) | VAF 87/92 reads (95%) | hotspot (GDC flag); catalogued as COSV54056313, COSV54065206, COSV54069334, COSV54070989; called by mutect2, pindel*
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 11/55 reads (20%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CYYR1 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.013); catalogued as rs373162538, COSV54831775; called by muse, mutect2, varscan2
- DNMT3A | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747448117, COSV53036167; called by muse, mutect2, varscan2
- MIB1 | c.1663C>A p.H555N | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.708); catalogued as COSV99838192; called by muse, mutect2
- CDH18 | c.40G>A p.V14M | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.03); called by muse, varscan2
- CENPA | c.283_288+3del p.X95_splice | Splice Site (DEL) | VAF 33/81 reads (41%) | called by mutect2, pindel, varscan2
- COL8A2 | c.306G>T p.M102I | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- DDX6 | c.1292_1294dup p.L431_G432insV | In Frame Ins (INS) | VAF 19/57 reads (33%) | called by mutect2, varscan2
- HGS | c.1588C>A p.Q530K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2
- ITGB1 | c.562G>T p.V188L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2
- NDRG2 | c.949+1G>A p.X317_splice (on ENST00000298687 / NM_001354570.1; = p.X303_splice on NM_016250.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 56/102 reads (55%) | called by muse, mutect2, varscan2
- TNR | c.677G>T p.S226I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- ZNF19 | c.784A>C p.I262L | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2
- CLK1 | c.1440G>A p.L480= | Silent (SNP) | VAF 57/112 reads (51%) | catalogued as COSV58434135; called by muse, mutect2, varscan2
- NUP153 | c.1737A>G p.T579= | Silent (SNP) | VAF 41/84 reads (49%) | catalogued as rs368424345; called by muse, mutect2, varscan2
- SNTB2 | c.426C>T p.I142= | Silent (SNP) | VAF 25/47 reads (53%) | called by muse, mutect2, varscan2
